Somatic mutation profile of tumor specimen TCGA-G4-6298-01A (aliquot TCGA-G4-6298-01A-11D-1719-10) from TCGA case TCGA-G4-6298, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-G4-6298-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3334cc8c-9104-4637-84e4-61a4cc3b5fb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6298-10A (Blood Derived Normal), aliquot TCGA-G4-6298-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00f05757-96c3-40e7-be6b-e1765253e050

The open-access MAF lists 80 somatic variants for this specimen: 62 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 17, Nonsense Mutation 5, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 36/125 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 69/178 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/69 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.4238G>A p.R1413H (on ENST00000614293; = p.R1383H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs772864842, COSV55805728; called by muse, mutect2
- ABCA3 | c.4214C>T p.A1405V | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs149559041; called by muse, mutect2, varscan2
- ALLC | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as rs755429246, COSV52994164, COSV99378331; called by muse, mutect2, varscan2
- AMER1 | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 49/77 reads (64%) | catalogued as COSV57666229; called by muse, mutect2, varscan2
- ASB18 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 89/316 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV68961073; called by muse, mutect2, varscan2
- B3GALT1 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764184986, COSV59909664; called by muse, mutect2, varscan2
- CACNG2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.747); catalogued as rs768099799, COSV55639973; called by muse, varscan2
- CHST2 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV58886849; called by muse, mutect2, varscan2
- COL6A3 | c.5777C>T p.T1926M | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs763172498, COSV55095463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.8500G>A p.G2834R (on ENST00000297405 / NM_001363185.1; = p.G2665R on NM_052900.3) | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs765870707, COSV52291510; called by muse, mutect2, varscan2
- DCAF4L2 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV60481714; called by muse, mutect2, varscan2
- DROSHA | c.1645C>T p.H549Y | Missense Mutation (SNP) | VAF 193/323 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60781563; called by muse, mutect2, varscan2
- EIF1AX | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63309369; called by muse, mutect2, varscan2
- EIF3B | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs772725989, COSV100703484, COSV62804598; called by muse, mutect2, varscan2
- EPRS1 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761087757, COSV65101166; called by muse, mutect2, varscan2
- FAM83G | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762729338, COSV58761399; called by muse, mutect2, varscan2
- FCGRT | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55528834, COSV55530767; called by muse, mutect2, varscan2
- FNDC8 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs199607691, COSV50100920; called by muse, mutect2, varscan2
- FTCD | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs749659966, COSV52429121; called by muse, mutect2, varscan2
- HDAC5 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56817626; called by muse, mutect2, varscan2
- ITGA4 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 120/406 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51998303, COSV52002278, COSV52003390; called by muse, mutect2, varscan2
- KLK15 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV56826514; called by muse, mutect2, varscan2
- KRTAP10-2 | c.196G>C p.A66P | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200799981, COSV59956008; called by muse, mutect2
- LINGO2 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV58063387; called by muse, mutect2, varscan2
- LIPC | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs371396620; called by muse, mutect2, varscan2
- LRFN5 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); catalogued as rs762294951, COSV53248846; called by muse, mutect2, varscan2
- LRP1B | c.7624G>T p.E2542* | Nonsense Mutation (SNP) | VAF 33/118 reads (28%) | catalogued as COSV67259269, COSV67264281; called by muse, mutect2, varscan2
- MFRP | c.407G>A p.C136Y (on ENST00000449574; = p.C512Y on NM_031433.4) | Missense Mutation (SNP) | VAF 92/148 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165509211, COSV60991309; called by muse, mutect2, varscan2
- MICAL3 | c.5814G>A p.M1938I | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52811644; called by muse, mutect2, varscan2
- MTOR | c.3238C>T p.R1080C | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs751901845, COSV63868492; called by muse, mutect2, varscan2
- MUC16 | c.23366C>A p.S7789Y | Missense Mutation (SNP) | VAF 259/824 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV67487915; called by muse, mutect2, varscan2
- MYBPC2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.097); catalogued as COSV63099181; called by muse, mutect2, varscan2
- MYO1F | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs370908051; called by muse, mutect2, varscan2
- MYO5C | c.4042+2T>C p.X1348_splice | Splice Site (SNP) | VAF 199/701 reads (28%) | catalogued as COSV55910218; called by muse, mutect2, varscan2
- NLRP10 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1442127677, COSV60782149; called by muse, mutect2, varscan2
- NRG1 | c.1636C>T p.R546W (on ENST00000405005 / NM_013964.5; = p.R551W on NM_013956.5) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs114185597, COSV55163692, COSV55167519; called by muse, mutect2, varscan2
- OR10AG1 | c.696C>G p.C232W | Missense Mutation (SNP) | VAF 96/155 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56634404; called by muse, mutect2, varscan2
- OR13C5 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 152/534 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.666); catalogued as COSV66165252; called by muse, mutect2, varscan2
- OR5B3 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs369150581, COSV58678429; called by muse, mutect2, varscan2
- PARP3 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs774210062, COSV51756050; called by muse, mutect2, varscan2
- PDE2A | c.391C>G p.P131A | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1352855638, COSV57812416; called by muse, mutect2
- PSMD2 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 56/167 reads (34%) | catalogued as COSV59531060; called by muse, mutect2, varscan2
- RAB25 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs566252037, COSV63107659; called by muse, mutect2, varscan2
- RFC4 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56218335; called by muse, mutect2, varscan2
- RGS22 | c.1423T>C p.S475P | Missense Mutation (SNP) | VAF 421/870 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.36); catalogued as rs774904357, COSV62666532; called by muse, mutect2, varscan2
- SH2D3C | c.1327G>A p.A443T (on ENST00000314830 / NM_170600.3; = p.A286T on NM_005489.4) | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs61761896; called by muse, mutect2, varscan2
- SMPD2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150792146; called by muse, mutect2, varscan2
- TCF7L2 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 35/117 reads (30%) | catalogued as COSV60503242; called by muse, mutect2, varscan2
- TGIF1 | c.187T>G p.C63G (on ENST00000330513 / NM_001374396.1; = p.C83G on NM_003244.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV57909329; called by muse, mutect2, varscan2
- TSSK1B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 73/115 reads (63%) | SIFT tolerated (0.93); PolyPhen benign (0.072); catalogued as rs1290786566, COSV66815933; called by muse, mutect2, varscan2
- TUBB2A | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as COSV61319458; called by muse, mutect2, varscan2
- TXNRD1 | c.890G>A p.G297D (on ENST00000525566 / NM_001093771.3; = p.G199D on NM_003330.4) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV61601069; called by muse, mutect2, varscan2
- UBE4B | c.3821C>T p.T1274M (on ENST00000343090 / NM_001105562.3; = p.T1145M on NM_006048.5) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs758014435, COSV53540496; called by muse, mutect2, varscan2
- WDPCP | c.2161G>A p.G721R | Missense Mutation (SNP) | VAF 99/398 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs563554007, COSV55414235; called by muse, mutect2, varscan2
- ZNF280B | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 170/521 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.166); catalogued as rs767294839, COSV64529519; called by muse, mutect2, varscan2
- APC | c.3860_3861dup p.G1288* | Frame Shift Ins (INS) | VAF 135/288 reads (47%) | called by mutect2, pindel, varscan2
- ATG2A | c.5570_5571del p.T1857Sfs*14 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | called by pindel, varscan2
- KLHL9 | c.346dup p.S116Ffs*3 | Frame Shift Ins (INS) | VAF 52/191 reads (27%) | called by mutect2, pindel, varscan2
- NPC1 | c.2911+2T>C p.X971_splice | Splice Site (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- ABCA13 | c.13593T>A p.T4531= | Silent (SNP) | VAF 195/840 reads (23%) | catalogued as COSV101291333; called by muse, mutect2, varscan2
- ACSS1 | c.2013C>T p.I671= | Silent (SNP) | VAF 66/312 reads (21%) | catalogued as rs755229997, COSV60224179; called by muse, mutect2, varscan2
- AP5Z1 | c.1404C>T p.H468= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs572309942, COSV62243419; called by muse, mutect2, varscan2
- BTBD11 | c.1848C>T p.D616= (on ENST00000280758 / NM_001018072.2; = p.D153= on NM_001017523.2) | Silent (SNP) | VAF 62/166 reads (37%) | catalogued as rs745602987, COSV55034778; called by muse, mutect2, varscan2
- CCDC9B | c.189C>T p.D63= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as rs777883742, COSV66876132; called by muse, mutect2, varscan2
- COLEC11 | c.183C>T p.V61= | Silent (SNP) | VAF 86/346 reads (25%) | catalogued as rs369069794; called by muse, mutect2, varscan2
- DLX5 | c.69G>A p.T23= | Silent (SNP) | VAF 52/244 reads (21%) | catalogued as COSV56031843; called by muse, mutect2, varscan2
- ENGASE | c.702C>A p.I234= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV56137444; called by muse, mutect2, varscan2
- GDF10 | c.1413C>T p.S471= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs782253093; called by muse, mutect2, varscan2
- HYDIN | c.8250C>T p.G2750= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs768556270, COSV99992495; called by muse, varscan2
- KIF1A | c.3297G>A p.S1099= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as rs762545111, COSV57499335; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT31 | c.678C>T p.N226= | Silent (SNP) | VAF 55/220 reads (25%) | catalogued as rs760988195, COSV52435427; called by muse, mutect2, varscan2
- NPHP4 | c.1605C>T p.A535= | Silent (SNP) | VAF 86/179 reads (48%) | catalogued as COSV100976877, COSV65397218; called by muse, mutect2, varscan2
- PIGO | c.1648C>T p.L550= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as COSV53055035; called by muse, mutect2, varscan2
- PKD1L1 | c.7494G>A p.T2498= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs553682583, COSV51841537; called by muse, mutect2, varscan2
- PKN3 | c.333G>T p.R111= | Silent (SNP) | VAF 72/272 reads (26%) | catalogued as COSV52579306; called by muse, mutect2, varscan2
- TRPM2 | c.2352C>T p.P784= | Silent (SNP) | VAF 68/246 reads (28%) | catalogued as rs143061056, COSV55975862; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840756 G>A | 5'Flank (SNP) | VAF 12/58 reads (21%) | catalogued as rs769719956, COSV58331089; called by muse, mutect2
